CCDI case PBCEKK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1b5903c9-a143-4820-9aa7-a02396883ea5

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.0 years (6,561 days).

Biospecimens (3 samples)
- Samples 0DQ2N2, 0DQ2NG (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ2OZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
